TCGA case TCGA-XT-AASU — Mesothelioma (TCGA-MESO)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Mesothelial Neoplasms; Primary site: Heart, mediastinum, and pleura; Tissue source site: Johns Hopkins. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a48996be-7dae-451a-8129-9de8dfe7221a

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 60 years; Vital status: Dead; Days to death: 142 days.

Diagnoses (4)
1. Mesothelioma, biphasic, malignant (the primary disease): ICD-O-3 morphology code: 9053/3; ICD-10 code: C45.0; Tissue or organ of origin: Pleura, NOS; Site of resection or biopsy: Pleura, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 60.3 years (22,021 days); Year of diagnosis: 2005; AJCC staging edition: 6th; AJCC pathologic T: T3; AJCC pathologic N: NX; AJCC pathologic M: MX; AJCC pathologic stage: Stage III; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant.
   Recorded as not given: Pleurodesis, NOS, prior to procurement; adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Mesothelioma, biphasic, malignant), site: Thorax, NOS. Age at diagnosis: 60.7 years (22,154 days); Days to diagnosis: 133 days; Prior treatment: Yes.
3. Metastasis of diagnosis 1 (Mesothelioma, biphasic, malignant), site: Abdomen, NOS. Age at diagnosis: 60.7 years (22,154 days); Days to diagnosis: 133 days; Prior treatment: Yes.
4. Metastasis of diagnosis 1 (Mesothelioma, biphasic, malignant), site: Bone, NOS. Age at diagnosis: 60.7 years (22,154 days); Days to diagnosis: 133 days; Prior treatment: Yes.

Follow-up (5 entries)
- Day 133 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Bone, NOS; Days to progression: 133 days.
- Day 133 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Abdomen, NOS; Days to progression: 133 days.
- Day 133 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Thorax, NOS; Days to recurrence: 133 days.
- Days to follow up: 142 days; Disease response: With Tumor.
- Karnofsky performance status: 80; ECOG performance status: 2; Timepoint: Preoperative.

Exposures
- Exposure type: Asbestos.
- Occupation type: Sheet and Structural Metal Workers, Moulders and Welders, and Related Workers.

Family history
- Relative with cancer history: yes; Relationship type: Parent; Relationship primary diagnosis: Bone Cancer.
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Ovarian Cancer.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-XT-AASU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 160 mg.
  Slide TCGA-XT-AASU-01A-01-TS1: Section location: Top; Percent tumor cells: 27; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 3; Percent stromal cells: 70; Percent lymphocyte infiltration: 15; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 0.
- Sample TCGA-XT-AASU-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-XT-AASU-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 160 mg.
  Slide TCGA-XT-AASU-11A-01-TSA: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 1; Percent necrosis: 0; Percent stromal cells: 99; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Pleurodesis performed prior: No; Tumor status: With tumor; History asbestos exposure: Yes; Primary occupation: Other, please specify; Occupation primary: sheet mill worker.
- Primary pathology: Submitted tumor site: Pleura; Histologic diagnosis: Biphasic mesothelioma.

GDC annotations on this case (curator notes; quoted as recorded):
- Neoadjuvant therapy: After adding pharmaceutical forms it was discovered that this patient received Cisplatin and Pemetrexed 2 months prior to the TCGA cancer procurement.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 142 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 142 days; disease-free interval: event (new tumor event after initially disease-free), 133 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 133 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-XT-AASU-01A-11D-A39Q-01): tumor purity 0.41, ploidy 1.98, whole-genome doublings 0.
